Somatic mutation profile of tumor specimen TCGA-AA-3713-01A (aliquot TCGA-AA-3713-01A-21D-1719-10) from TCGA case TCGA-AA-3713, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 68.2 years (24,927 days).
Specimen TCGA-AA-3713-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e920b5dd-8297-4e7e-a92a-00ab99de48e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3713-11A (Solid Tissue Normal), aliquot TCGA-AA-3713-11A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15b45d2f-f4c7-4cde-b591-6e3a1b67ea39

The open-access MAF lists 1,223 somatic variants for this specimen: 958 protein-altering or splice-affecting, 238 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 624, Silent 238, Frame Shift Del 197, Frame Shift Ins 72, Nonsense Mutation 26, Splice Site 18, Intron 14, In Frame Del 9, Splice Region 8, RNA 7, 3'UTR 4, Translation Start Site 3.

Variants (750 of 1,223; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 30/137 reads (22%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BSCL2 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as rs587777606, CS134831, COSV54015330; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1A | c.3423del p.K1142Rfs*48 | Frame Shift Del (DEL) | VAF 44/221 reads (20%) | catalogued as rs746790849; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CDK12 | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 47/249 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71000029; called by muse, mutect2, varscan2
- CFAP20 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 61/211 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs753911484, COSV52630441; called by muse, mutect2, varscan2
- FAT4 | c.11461C>T p.R3821* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as rs398122957, CM1311053, COSV58680175; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GUCY2D | c.2513G>A p.R838H | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61750173, CM012606, HM080086, COSV54695753; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- LDLRAP1 | c.603dup p.S202Lfs*19 | Frame Shift Ins (INS) | VAF 14/88 reads (16%) | catalogued as rs781585299; ClinVar: pathogenic; called by pindel, varscan2
- SDHB | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138996609, CM034573, COSV64965126; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TOP3A | c.2271del p.R758Gfs*15 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs752838075; ClinVar: pathogenic; called by mutect2, varscan2
- TYR | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs61753185, CM900220; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VPS13B | c.7322+2T>C p.X2441_splice | Splice Site (SNP) | VAF 28/124 reads (23%) | catalogued as rs1563908020, COSV62138972; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.5246T>A p.L1749Q | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54027825; called by muse, mutect2, varscan2
- ABCC12 | c.59C>A p.S20Y | Missense Mutation (SNP) | VAF 80/245 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV60913232, COSV60918352; called by muse, mutect2, varscan2
- ABHD4 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as rs148116289, COSV99360453; called by muse, mutect2, varscan2
- ABLIM1 | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53304233, COSV53304902; called by muse, mutect2, varscan2
- ABLIM1 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV53304277; called by muse, mutect2, varscan2
- ABLIM3 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs186503737, COSV100448095; called by muse, mutect2, varscan2
- ABTB2 | c.2332_2334del p.E778del | In Frame Del (DEL) | VAF 18/92 reads (20%) | catalogued as rs767544640; called by pindel, varscan2
- ACAN | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs777066916, COSV61359181; called by muse, mutect2, varscan2
- ACBD5 | c.104C>G p.A35G (on ENST00000375888 / NM_001352568.1; = p.A37G on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as COSV65518768, COSV65520157; called by muse, mutect2, varscan2
- ACER2 | c.58T>G p.C20G | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61820660; called by muse, mutect2, varscan2
- ACER3 | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV53598398; called by muse, mutect2, varscan2
- ACP2 | c.878del p.L293Rfs*89 | Frame Shift Del (DEL) | VAF 33/133 reads (25%) | catalogued as COSV57037926; called by mutect2, pindel, varscan2
- ACP7 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766788180, COSV100488541; called by muse, mutect2, varscan2
- ACSF2 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV51972012; called by muse, mutect2, varscan2
- ACSS1 | c.1419C>G p.F473L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV60219399; called by muse, mutect2, varscan2
- ACTR6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 39/119 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV51841619, COSV51841650; called by muse, mutect2, varscan2
- ADAM18 | c.710G>T p.W237L | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55846193; called by muse, mutect2, varscan2
- ADAMTS18 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV51404820; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4162G>A p.A1388T | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs373837581; called by muse, mutect2, varscan2
- ADARB1 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV62343717; called by muse, mutect2, varscan2
- ADORA1 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1019929241, COSV58809874; called by muse, mutect2, varscan2
- ADORA1 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as rs748346254, COSV55142085; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADRA1A | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 78/354 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.168); catalogued as rs1563237349, COSV52361925; called by muse, mutect2, varscan2
- ADSS1 | c.1122A>T p.K374N | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV58273071; called by muse, mutect2, varscan2
- AEBP1 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56256987; called by muse, mutect2, varscan2
- AFF4 | c.989del p.P330Lfs*2 | Frame Shift Del (DEL) | VAF 32/181 reads (18%) | catalogued as COSV99535178; called by mutect2, pindel, varscan2
- AGO4 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369348803, COSV100942927, COSV64616907; called by muse, mutect2, varscan2
- AHDC1 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs773993918, COSV55938072; called by muse, mutect2, varscan2
- AHNAK | c.11924T>C p.V3975A | Missense Mutation (SNP) | VAF 74/274 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV57210791; called by muse, mutect2, varscan2
- AHRR | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs201569519, COSV57084895; called by muse, mutect2, varscan2
- AIFM3 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as COSV58998846; called by muse, mutect2, varscan2
- AKR1B15 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs758195535, COSV71151588; called by muse, mutect2, varscan2
- ALDH3A1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as COSV56735029; called by muse, mutect2, varscan2
- ALOX15 | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 31/139 reads (22%) | catalogued as COSV53397222; called by muse, mutect2, varscan2
- ALS2CL | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 38/155 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV59671022; called by muse, mutect2, varscan2
- ANGPTL6 | c.1061del p.G354Afs*115 | Frame Shift Del (DEL) | VAF 23/96 reads (24%) | catalogued as rs766045464; called by mutect2, pindel, varscan2
- ANKRD12 | c.800T>G p.V267G | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50822698; called by muse, mutect2, varscan2
- ANKRD20A2P | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 46/388 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs749215832, COSV101111860; called by muse, mutect2, varscan2
- ANKRD27 | c.2623C>T p.R875W | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs148470330; called by muse, mutect2, varscan2
- ANKS1B | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 54/225 reads (24%) | catalogued as COSV61346172; called by muse, mutect2, varscan2
- ANO10 | c.1293+1G>A p.X431_splice | Splice Site (SNP) | VAF 256/1018 reads (25%) | catalogued as COSV99428681; called by muse, varscan2
- AP2A2 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs199955220, COSV59959730; called by muse, mutect2, varscan2
- APEH | c.1527del p.X509_splice | Splice Site (DEL) | VAF 83/321 reads (26%) | catalogued as rs1255876232; called by mutect2, pindel, varscan2
- APOB | c.1375G>T p.G459W | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.475); catalogued as COSV51931913; called by muse, mutect2, varscan2
- APOBR | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV60490007; called by muse, mutect2, varscan2
- APOC4 | c.269T>G p.L90R | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52990145; called by muse, mutect2, varscan2
- ARFGEF1 | c.4613C>T p.A1538V | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1045151994, COSV51606599; called by muse, mutect2, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 70/343 reads (20%) | catalogued as rs773922861; called by pindel, varscan2
- ARHGEF10L | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs776331349, COSV51430988; called by muse, mutect2, varscan2
- ARHGEF11 | c.863A>C p.K288T | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV63811717; called by muse, mutect2, varscan2
- ARHGEF17 | c.4949C>T p.T1650M | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs756636153, COSV99736002; called by muse, mutect2
- ARID2 | c.5239G>T p.G1747* | Nonsense Mutation (SNP) | VAF 73/230 reads (32%) | catalogued as COSV57600337; called by muse, mutect2, varscan2
- ASAP1 | c.903G>C p.Q301H | Missense Mutation (SNP) | VAF 161/727 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs1385863686, COSV63047323, COSV63052150; called by muse, mutect2, varscan2
- ASB16 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as rs368804726, COSV53234588; called by muse, mutect2, varscan2
- ASH1L | c.8029C>T p.R2677C (on ENST00000368346 / NM_001366177.2; = p.R2672C on NM_018489.3) | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1037890253, COSV64207172; called by muse, mutect2, varscan2
- ASH1L | c.2951G>A p.R984H | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.747); catalogued as rs1187547460, COSV64207177; called by muse, mutect2, varscan2
- ASPHD2 | c.333del p.E112Sfs*109 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | catalogued as COSV53218679; called by mutect2, varscan2
- ASTE1 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53908430; called by muse, mutect2, varscan2
- ATG4D | c.359T>G p.L120R | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58762425; called by muse, mutect2, varscan2
- ATG9B | c.293del p.P98Qfs*8 | Frame Shift Del (DEL) | VAF 119/270 reads (44%) | catalogued as rs770350293; called by mutect2, pindel, varscan2
- ATP10A | c.3793A>G p.M1265V | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs756615990, COSV63516224; called by muse, mutect2, varscan2
- ATP11A | c.1497del p.K500Nfs*27 | Frame Shift Del (DEL) | VAF 13/126 reads (10%) | catalogued as rs1566546408, COSV52105595; called by mutect2, pindel, varscan2
- ATP13A5 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs776380026, COSV60868282; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776545761, COSV52353294; called by muse, mutect2, varscan2
- ATP8B3 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749622913, COSV59541965; called by muse, mutect2, varscan2
- ATR | c.1364A>G p.D455G | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.368); catalogued as rs776069964, COSV63385740; called by muse, mutect2, varscan2
- ATXN3L | c.139A>G p.R47G | Missense Mutation (SNP) | VAF 62/112 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV66075559; called by muse, mutect2, varscan2
- AWAT2 | c.85+2T>C p.X29_splice | Splice Site (SNP) | VAF 29/54 reads (54%) | catalogued as COSV52143196; called by muse, mutect2, varscan2
- BANP | c.946C>T p.R316C (on ENST00000286122; = p.R285C on NM_017869.4) | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53736478; called by muse, varscan2
- BAZ1A | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as rs756584573, COSV62409855; called by muse, varscan2
- BAZ2A | c.776_785del p.V259Dfs*14 | Frame Shift Del (DEL) | VAF 21/113 reads (19%) | catalogued as COSV51635034; called by mutect2, pindel, varscan2
- BCL9L | c.1346del p.P449Lfs*14 | Frame Shift Del (DEL) | VAF 38/119 reads (32%) | catalogued as rs754310793, COSV52681762; called by mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 31/68 reads (46%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BCR | c.2981C>T p.T994M | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as rs550045049, COSV59930244; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 143/272 reads (53%) | catalogued as rs755506199; called by mutect2, varscan2
- BLMH | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55585130; called by muse, mutect2, varscan2
- BLMH | c.67dup p.Q23Pfs*71 | Frame Shift Ins (INS) | VAF 25/144 reads (17%) | catalogued as rs748478324; called by mutect2, pindel, varscan2
- BMP2 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.571); catalogued as rs756645581, COSV66577524; called by muse, mutect2, varscan2
- BMPR1B | c.158G>T p.C53F | Missense Mutation (SNP) | VAF 91/357 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52776457; called by muse, mutect2, varscan2
- BRD8 | c.3488G>A p.R1163H | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs757840348, COSV54522018; called by muse, mutect2, varscan2
- BRF1 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1237080721, COSV59267955; called by muse, mutect2, varscan2
- BRINP1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 120/498 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs201491506, COSV56292208; called by muse, varscan2
- BRINP1 | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 102/438 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs374373152; called by muse, varscan2
- BRINP2 | c.2044A>G p.T682A | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV64176976; called by muse, mutect2, varscan2
- BRMS1L | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.036); catalogued as COSV53762959; called by muse, varscan2
- BRPF3 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60206894; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 13/129 reads (10%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BUB1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.932); catalogued as rs759283101, COSV57062866; called by muse, mutect2, varscan2
- C1S | c.1597G>A p.V533M | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV61070682; called by muse, varscan2
- C1orf94 | c.1051A>C p.S351R (on ENST00000488417 / NM_001134734.2; = p.S161R on NM_032884.5) | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV64913739; called by muse, mutect2, varscan2
- C9orf78 | c.723_725del p.E242del | In Frame Del (DEL) | VAF 50/202 reads (25%) | catalogued as rs1275920507; called by pindel, varscan2
- CABLES2 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 141/563 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs371230015; called by muse, mutect2, varscan2
- CACNA1G | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.237); catalogued as rs370667544, COSV61724714; called by muse, mutect2, varscan2
- CACNA1G | c.6948del p.E2317Rfs*47 | Frame Shift Del (DEL) | VAF 23/112 reads (21%) | catalogued as rs766047428; called by mutect2, varscan2
- CACNA2D4 | c.2171G>T p.R724L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as COSV54948461; called by muse, mutect2, varscan2
- CADM3 | c.653G>A p.G218E (on ENST00000368125 / NM_001127173.3; = p.G252E on NM_021189.5) | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.102); catalogued as COSV63684792; called by muse, mutect2, varscan2
- CALHM1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.738); catalogued as rs374702244; called by muse, mutect2, varscan2
- CAMK1D | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 76/245 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257797457, COSV66610289; called by muse, mutect2, varscan2
- CAMK2G | c.221-1G>A p.X74_splice | Splice Site (SNP) | VAF 26/101 reads (26%) | catalogued as COSV59481256; called by muse, mutect2, varscan2
- CAMSAP1 | c.4349C>T p.S1450L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs898676954, COSV56721387; called by muse, varscan2
- CAMTA2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 39/170 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); catalogued as COSV100742047; called by muse, mutect2, varscan2
- CAPG | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs566538644, COSV55707124; called by muse, mutect2, varscan2
- CARD9 | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53732417; called by muse, mutect2, varscan2
- CARMIL3 | c.2822del p.P941Lfs*31 | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | catalogued as rs773353274, COSV57724683; called by mutect2, pindel, varscan2
- CARS1 | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1461372759, COSV53453285; called by muse, mutect2, varscan2
- CASKIN2 | c.2182del p.Q728Rfs*74 | Frame Shift Del (DEL) | VAF 36/134 reads (27%) | catalogued as rs751998890, COSV100051067; called by mutect2, varscan2
- CATSPER1 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV56409291, COSV56410101; called by muse, mutect2
- CATSPER3 | c.488T>A p.I163N | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV50945935; called by muse, mutect2, varscan2
- CATSPERE | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 82/271 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.034); catalogued as rs774437688, COSV63677324, COSV63683272; called by muse, mutect2, varscan2
- CBLN3 | c.206del p.P69Lfs*35 | Frame Shift Del (DEL) | VAF 149/339 reads (44%) | catalogued as rs1268177561; called by mutect2, pindel, varscan2
- CBX8 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53935593; called by muse, mutect2, varscan2
- CBY2 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV60117901; called by muse, mutect2
- CCDC116 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs749932957, COSV53037473; called by muse, mutect2, varscan2
- CCDC14 | c.1088A>T p.D363V (on ENST00000488653; = p.D315V on NM_022757.5) | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV59944104; called by muse, mutect2, varscan2
- CCDC157 | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369961135; called by muse, mutect2
- CCDC173 | c.1109dup p.N370Kfs*19 | Frame Shift Ins (INS) | VAF 104/356 reads (29%) | catalogued as rs1425656393; called by mutect2, varscan2
- CCDC180 | c.154A>G p.M52V | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs770361437, COSV63829287; called by muse, mutect2, varscan2
- CCDC9 | c.1413C>A p.F471L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV55720360; called by muse, mutect2, varscan2
- CCKBR | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV58100535, COSV58103786; called by muse, mutect2, varscan2
- CCR2 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 114/420 reads (27%) | catalogued as rs1454368903, COSV52747915; called by muse, mutect2, varscan2
- CD1E | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs745887326, COSV63770740; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 11/92 reads (12%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD40LG | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as CM960263, COSV65698387; called by muse, mutect2, varscan2
- CD55 | c.992C>T p.T331I | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs143471404; called by muse, mutect2, varscan2
- CDAN1 | c.808T>C p.C270R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.048); catalogued as COSV51159306; called by muse, mutect2, varscan2
- CDC25A | c.206G>C p.S69T | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.155); catalogued as COSV56770383; called by muse, mutect2, varscan2
- CDC42BPA | c.2605C>T p.R869C | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62009181; called by muse, mutect2, varscan2
- CDH5 | c.2172dup p.Y725Lfs*30 | Frame Shift Ins (INS) | VAF 24/75 reads (32%) | catalogued as rs781713547; called by mutect2, varscan2
- CDX2 | c.916del p.V306Cfs*2 | Frame Shift Del (DEL) | VAF 22/91 reads (24%) | catalogued as rs773511514; called by mutect2, pindel, varscan2
- CDYL | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1280593516, COSV100189587; called by muse, mutect2, varscan2
- CELSR1 | c.5544del p.T1849Rfs*8 | Frame Shift Del (DEL) | VAF 28/126 reads (22%) | catalogued as rs776824429; called by mutect2, varscan2
- CELSR1 | c.3202C>T p.R1068W | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs759999324, COSV53087927; called by muse, mutect2, varscan2
- CERK | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs144086274, COSV53450899; called by muse, mutect2, varscan2
- CERS1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs374895377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CERS2 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV54980824; called by muse, mutect2, varscan2
- CES1 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745776203, COSV62086559; called by muse, mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 58/226 reads (26%) | catalogued as rs1561489348; called by mutect2, pindel, varscan2
- CHD2 | c.1618G>A p.V540I | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs1368222485, COSV67708304; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CHD3 | c.3563C>T p.A1188V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV57873204, COSV57874208; called by muse, mutect2, varscan2
- CHN1 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as COSV55032931; called by muse, mutect2, varscan2
- CHRM2 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 98/383 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57769875; called by muse, mutect2, varscan2
- CILK1 | c.1876C>T p.H626Y (on ENST00000350082 / NM_001375397.1; = p.H619Y on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63153965; called by muse, mutect2, varscan2
- CIP2A | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs1164937135, COSV55418322; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 36/105 reads (34%) | catalogued as rs752250702; called by mutect2, varscan2
- CLK3 | c.883C>T p.R295W (on ENST00000395066 / NM_001130028.1; = p.R147W on NM_003992.4) | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs751508782, COSV100775866, COSV61412327; called by muse, mutect2, varscan2
- CLNK | c.1114C>A p.L372M | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1424576791, COSV57013781; called by muse, mutect2, varscan2
- CLSTN3 | c.2624G>A p.R875H | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs199822119; called by muse, mutect2, varscan2
- CNGA4 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1364721825, COSV66005665; called by muse, mutect2
- CNIH3 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 62/396 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); catalogued as rs529360966, COSV55273475; called by muse, mutect2, varscan2
- CNOT8 | c.312-2A>T p.X104_splice | Splice Site (SNP) | VAF 36/128 reads (28%) | catalogued as COSV53585383; called by muse, mutect2, varscan2
- CNPY3 | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65709770; called by muse, mutect2, varscan2
- CNTN2 | c.2861A>T p.D954V | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs767209651, COSV59349538; called by muse, mutect2, varscan2
- CNTN6 | c.1082A>T p.E361V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV63168969; called by muse, mutect2, varscan2
- COBLL1 | c.2210G>A p.G737D (on ENST00000392717; = p.G699D on NM_014900.5) | Missense Mutation (SNP) | VAF 86/353 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs750021681, COSV52066426; called by muse, mutect2, varscan2
- COCH | c.434G>T p.R145M (on ENST00000216361 / NM_001347720.1; = p.R80M on NM_004086.3) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV53550387; called by muse, mutect2, varscan2
- COG4 | c.1811T>C p.F604S | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV55369796; called by muse, mutect2, varscan2
- COL15A1 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV66643543; called by muse, mutect2, varscan2
- COL1A2 | c.3244C>T p.P1082S | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV51956430; called by muse, mutect2, varscan2
- COMMD4 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV51190327; called by muse, mutect2, varscan2
- COPE | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV53230209; called by muse, mutect2, varscan2
- CPA1 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs375929600, COSV50568384; called by muse, mutect2, varscan2
- CPB2 | c.213dup p.V72Cfs*5 | Frame Shift Ins (INS) | VAF 39/162 reads (24%) | catalogued as rs1174947217; called by mutect2, varscan2
- CPPED1 | c.44del p.G15Afs*31 | Frame Shift Del (DEL) | VAF 30/122 reads (25%) | catalogued as rs759977975; called by mutect2, pindel, varscan2
- CR2 | c.1792C>A p.L598I | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV65507181; called by muse, mutect2, varscan2
- CRY2 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs1218096020, COSV69888390; called by muse, mutect2, varscan2
- CSAD | c.236G>A p.R79H (on ENST00000444623 / NM_001244705.2; = p.R106H on NM_015989.5) | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV57242169, COSV99914937; called by muse, mutect2, varscan2
- CSMD3 | c.1082A>G p.N361S | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV52155811; called by muse, mutect2, varscan2
- CSNK1A1 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as COSV55793909; called by muse, mutect2, varscan2
- CYLC2 | c.17T>C p.F6S | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV66337193; called by muse, mutect2, varscan2
- CYP2C19 | c.1084A>G p.I362V | Missense Mutation (SNP) | VAF 64/262 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64907482; called by muse, mutect2, varscan2
- CYP4A11 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV60223059; called by muse, mutect2, varscan2
- CYTIP | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1048200362, COSV51633338, COSV51635231; called by muse, mutect2, varscan2
- DAPL1 | c.127dup p.T43Nfs*23 | Frame Shift Ins (INS) | VAF 43/226 reads (19%) | catalogued as rs763165810; called by mutect2, varscan2
- DBN1 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753006714, COSV52789084; called by muse, mutect2, varscan2
- DCAF12L1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 138/249 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs748351807, COSV64421400, COSV64421892; called by muse, mutect2, varscan2
- DCAF12L2 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.425); catalogued as rs1323651448, COSV63581201; called by muse, mutect2, varscan2
- DCAF4L1 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); catalogued as rs143365042; called by muse, mutect2, varscan2
- DCST1 | c.174dup p.L59Afs*121 | Frame Shift Ins (INS) | VAF 19/81 reads (23%) | catalogued as rs746224810; called by mutect2, varscan2
- DCTN5 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs764481027, COSV55615151; called by muse, mutect2, varscan2
- DDX51 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57957944; called by muse, mutect2, varscan2
- DDX54 | c.2201del p.R734Lfs*97 | Frame Shift Del (DEL) | VAF 47/205 reads (23%) | catalogued as COSV58372987; called by mutect2, pindel, varscan2
- DEFA6 | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52405910; called by muse, mutect2, varscan2
- DENND4B | c.3410G>A p.R1137H | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs752580121, COSV63408412; called by muse, mutect2, varscan2
- DENND5B | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs765355515, COSV60901866; called by muse, mutect2, varscan2
- DHRS12 | c.736G>A p.A246T (on ENST00000444610 / NM_001377930.1; = p.A197T on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.068); catalogued as rs143366927, COSV54470993; called by muse, mutect2, varscan2
- DIDO1 | c.6596G>A p.R2199Q | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); catalogued as rs1271481460, COSV56614350; called by muse, mutect2, varscan2
- DIDO1 | c.3938C>T p.P1313L | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56619460; called by muse, mutect2, varscan2
- DKK2 | c.593A>G p.H198R | Missense Mutation (SNP) | VAF 55/267 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99569111; called by muse, mutect2, varscan2
- DLGAP2 | c.940G>A p.V314M | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as rs765184753, COSV70097069; called by muse, mutect2
- DMTN | c.252C>A p.R84= | Splice Region (SNP) | VAF 58/236 reads (25%) | catalogued as COSV56112242; called by muse, varscan2
- DMXL2 | c.2731C>T p.H911Y | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV51844532; called by muse, mutect2, varscan2
- DNAH17 | c.9671C>T p.P3224L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs767410940, COSV67752506; called by muse, mutect2
- DNAH17 | c.7354A>G p.M2452V | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67752508; called by muse, mutect2, varscan2
- DNAH17 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 77/265 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.651); catalogued as rs777329899, COSV67752513; called by muse, mutect2, varscan2
- DNAH5 | c.11528C>T p.S3843L | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs78346432, CM065132, COSV54202507; called by muse, mutect2, varscan2
- DNAJB13 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs376516482; called by muse, mutect2, varscan2
- DNALI1 | c.520C>T p.R174* (on ENST00000296218; = p.R152* on NM_003462.5) | Nonsense Mutation (SNP) | VAF 33/161 reads (20%) | catalogued as rs1198865054, COSV56169601; called by muse, mutect2, varscan2
- DNHD1 | c.13772G>T p.R4591L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV54433847, COSV54437579; called by muse, mutect2, varscan2
- DOC2A | c.191del p.P64Lfs*27 | Frame Shift Del (DEL) | VAF 29/127 reads (23%) | catalogued as rs753153258; called by mutect2, pindel, varscan2
- DOCK10 | c.4180G>T p.A1394S | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.324); catalogued as COSV51375979; called by muse, varscan2
- DOCK3 | c.1304G>A p.R435K | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.124); catalogued as COSV56515600, COSV56540639, COSV99815927; called by muse, mutect2, varscan2
- DOCK5 | c.3580G>A p.A1194T | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs186151980, COSV52399677; called by muse, mutect2, varscan2
- DPEP2 | c.120dup p.R41Qfs*26 | Frame Shift Ins (INS) | VAF 38/182 reads (21%) | catalogued as rs547189498; called by mutect2, varscan2
- DPP3 | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756979162, COSV57856482; called by muse, mutect2, varscan2
- DPP6 | c.2281G>A p.G761R (on ENST00000377770 / NM_001364500.2; = p.G699R on NM_001936.5) | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.7); catalogued as COSV100126433; called by muse, mutect2, varscan2
- DPYD | c.2909C>A p.A970D | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64595197; called by muse, mutect2, varscan2
- DRD1 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV67104458; called by muse, mutect2, varscan2
- DRD5 | c.925T>C p.W309R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100431863; called by muse, mutect2, varscan2
- DTX4 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV57089798; called by muse, mutect2, varscan2
- E2F4 | c.953G>A p.S318N | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.441); catalogued as rs201338753; called by muse, varscan2
- ECT2 | c.2717T>C p.L906S (on ENST00000392692 / NM_001349098.2; = p.L875S on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV51687982; called by muse, mutect2, varscan2
- EDEM2 | c.1410del p.Y471Tfs*21 | Frame Shift Del (DEL) | VAF 49/193 reads (25%) | catalogued as rs767540719; called by mutect2, pindel, varscan2
- EEF1A2 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.188); catalogued as COSV53205230; called by muse, mutect2, varscan2
- EFNB3 | c.991dup p.Q331Pfs*20 | Frame Shift Ins (INS) | VAF 31/98 reads (32%) | catalogued as rs756422375; called by mutect2, varscan2
- EHD1 | c.724A>G p.K242E | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57734410; called by muse, mutect2, varscan2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 38/152 reads (25%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EIF2B5 | c.844C>T p.R282* (on ENST00000647909; = p.R274* on NM_003907.3) | Nonsense Mutation (SNP) | VAF 30/130 reads (23%) | catalogued as rs1334515681, COSV56604298; called by muse, varscan2
- EIF3G | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs776642037, COSV53458022; called by muse, mutect2, varscan2
- ELAPOR2 | c.2102G>A p.G701D (on ENST00000450689 / NM_001142749.3; = p.G534D on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV51885828; called by muse, mutect2, varscan2
- ELAPOR2 | c.1491-1G>A p.X497_splice (on ENST00000450689 / NM_001142749.3; = p.X330_splice on NM_152748.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 47/195 reads (24%) | catalogued as COSV51885851; called by muse, mutect2, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 58/187 reads (31%) | catalogued as rs751148694; called by mutect2, varscan2
- ELK3 | c.446A>T p.N149I | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV57386274; called by muse, mutect2, varscan2
- EMC10 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs200217945, COSV58542152; called by muse, mutect2, varscan2
- EMP2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs370673124, COSV63995815; called by muse, mutect2, varscan2
- EMP2 | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as COSV63995820; called by muse, mutect2, varscan2
- EN1 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54630780; called by muse, mutect2, varscan2
- ENTPD7 | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138413355; called by muse, mutect2, varscan2
- EOMES | c.1729G>T p.G577C | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); catalogued as COSV55412103, COSV55413646; called by muse, mutect2, varscan2
- EP400 | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 70/275 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs377249323, COSV57764575; called by muse, varscan2
- EPB41L3 | c.2966C>T p.S989L | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138017302, COSV59444393; called by muse, mutect2, varscan2
- EPHB1 | c.2534del p.P845Hfs*34 | Frame Shift Del (DEL) | VAF 77/260 reads (30%) | catalogued as rs754939903; called by mutect2, pindel, varscan2
- EPHB1 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs749600936, COSV67655033; called by muse, mutect2, varscan2
- ERBB3 | c.2413del p.A805Hfs*95 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | catalogued as COSV57251045; called by mutect2, pindel, varscan2
- ERBB4 | c.3497T>A p.V1166E | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.832); catalogued as COSV61480314; called by muse, mutect2, varscan2
- ERBB4 | c.2236A>T p.I746F | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV53522975; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 38/152 reads (25%) | catalogued as rs775950025; called by mutect2, varscan2
- ESYT2 | c.1901G>A p.R634H (on ENST00000613624; = p.R558H on NM_020728.3) | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as rs777853347, COSV51750185; called by muse, mutect2, varscan2
- EXOC6B | c.673C>A p.Q225K | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.761); catalogued as COSV55551871; called by muse, mutect2, varscan2
- F2RL3 | c.974G>T p.S325I | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV50185383; called by muse, mutect2, varscan2
- FAIM2 | c.211A>T p.S71C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.293); catalogued as COSV57738919; called by muse, mutect2, varscan2
- FAM114A2 | c.725A>T p.D242V | Missense Mutation (SNP) | VAF 85/336 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61077571; called by muse, mutect2, varscan2
- FAM160B1 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs138422469, COSV65087282; called by muse, mutect2, varscan2
- FAM214B | c.1495C>A p.L499M | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59715687; called by muse, mutect2, varscan2
- FAM71B | c.1221C>G p.Y407* | Nonsense Mutation (SNP) | VAF 33/160 reads (21%) | catalogued as COSV57228559; called by muse, mutect2, varscan2
- FAM76B | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs565105324, COSV57688045; called by muse, mutect2
- FASTKD3 | c.428dup p.D144Gfs*3 | Frame Shift Ins (INS) | VAF 79/286 reads (28%) | catalogued as rs773607911; called by mutect2, varscan2
- FAT3 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs780559377, COSV53099415; called by muse, mutect2, varscan2
- FBLIM1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs757119431, COSV60029364; called by muse, mutect2, varscan2
- FBN3 | c.1597_1599del p.N533del | In Frame Del (DEL) | VAF 17/59 reads (29%) | catalogued as rs777117951; called by mutect2, pindel, varscan2
- FBXW7 | c.1877C>A p.A626D (on ENST00000281708 / NM_001349798.2; = p.A546D on NM_018315.5) | Missense Mutation (SNP) | VAF 78/123 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55906078, COSV55908924; called by muse, mutect2, varscan2
- FCAMR | c.196dup p.R66Kfs*103 | Frame Shift Ins (INS) | VAF 51/217 reads (24%) | catalogued as rs750132652; called by mutect2, pindel, varscan2
- FEN1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV57250713; called by muse, mutect2, varscan2
- FGF23 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs200445443, COSV52975670; called by muse, mutect2, varscan2
- FGFR2 | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 79/272 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1324703247, COSV60644906; called by muse, mutect2, varscan2
- FHOD1 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV50759939; called by muse, mutect2, varscan2
- FICD | c.130C>A p.L44M | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.548); catalogued as COSV64200745, COSV64200747; called by muse, mutect2
- FLI1 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs375383556; called by muse, mutect2, varscan2
- FLNB | c.5181G>T p.W1727C | Missense Mutation (SNP) | VAF 24/520 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.235); catalogued as COSV99913772; called by muse, mutect2
- FMN2 | c.2312del p.P771Lfs*17 | Frame Shift Del (DEL) | VAF 27/116 reads (23%) | catalogued as rs752691173, COSV60422852; called by mutect2, pindel, varscan2
- FMN2 | c.3029C>A p.P1010H | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV60421264, COSV60426866; called by muse, varscan2
- FN1 | c.3065C>T p.A1022V | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60549635, COSV60550676; called by muse, mutect2, varscan2
- FNBP4 | c.2752_2754dup p.P918dup | In Frame Ins (INS) | VAF 7/29 reads (24%) | catalogued as rs770556679; called by mutect2, varscan2
- FNBP4 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 131/589 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs1052503908, COSV55447873; called by muse, mutect2, varscan2
- FOLR3 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs746149373, COSV61531229; called by muse, mutect2, varscan2
- FOXA1 | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51647165; called by muse, mutect2, varscan2
- FOXB1 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1490898774, COSV68525750; called by muse, mutect2, varscan2
- FOXN3 | c.287dup p.S97Ifs*6 | Frame Shift Ins (INS) | VAF 12/52 reads (23%) | catalogued as rs760347049; called by mutect2, varscan2
- FPR1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as rs745998725, COSV100494147; called by muse, mutect2, varscan2
- FRZB | c.458T>A p.I153N | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54553810; called by muse, mutect2, varscan2
- GALNT14 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.318); catalogued as COSV100205031; called by muse, mutect2, varscan2
- GALNT6 | c.1557del p.K520Sfs*79 | Frame Shift Del (DEL) | VAF 68/246 reads (28%) | catalogued as rs748677519, COSV62541669; called by mutect2, pindel, varscan2
- GALNT8 | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV52896703; called by muse, mutect2, varscan2
- GAREM1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 197/366 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1422190759, COSV52505694; called by muse, mutect2, varscan2
- GARRE1 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs775494466, COSV55098454, COSV55098562; called by muse, mutect2, varscan2
- GATAD2A | c.92T>C p.M31T | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs1568310680, COSV53068838; called by muse, mutect2, varscan2
- GATAD2A | c.817del p.R273Gfs*42 | Frame Shift Del (DEL) | VAF 30/116 reads (26%) | catalogued as COSV53067075; called by mutect2, varscan2
- GBF1 | c.5536G>T p.A1846S (on ENST00000369983 / NM_001377137.1; = p.A1845S on NM_004193.3) | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV64144309; called by muse, mutect2, varscan2
- GCC2 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 80/277 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV59175685; called by muse, mutect2, varscan2
- GLRA3 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 72/138 reads (52%) | catalogued as rs201620617; called by muse, mutect2, varscan2
- GNAI3 | c.437A>T p.Y146F | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.447); catalogued as COSV63983584; called by muse, mutect2, varscan2
- GOLGA2 | c.104A>G p.K35R | Missense Mutation (SNP) | VAF 176/585 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60791885; called by muse, mutect2, varscan2
- GPR152 | c.611C>A p.P204H | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56886074; called by muse, mutect2
- GPR19 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1170556024, COSV60123318; called by muse, mutect2, varscan2
- GPR22 | c.108T>A p.Y36* | Nonsense Mutation (SNP) | VAF 81/255 reads (32%) | catalogued as COSV51748241; called by muse, mutect2, varscan2
- GPR37L1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs369524183; called by muse, mutect2, varscan2
- GPRASP1 | c.3532G>A p.A1178T | Missense Mutation (SNP) | VAF 65/104 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as rs1485238312, COSV64355369; called by muse, mutect2, varscan2
- GPS1 | c.62T>G p.V21G | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV57648608; called by muse, mutect2, varscan2
- GRIK2 | c.2081del p.F694Sfs*16 | Frame Shift Del (DEL) | VAF 24/120 reads (20%) | catalogued as COSV59762502; called by mutect2, pindel, varscan2
- GRIK3 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV66138266; called by muse, mutect2, varscan2
- GRIN2A | c.4021del p.S1341Afs*56 | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | catalogued as COSV58051797; called by mutect2, pindel, varscan2
- GRM6 | c.1289G>A p.C430Y | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51439044; called by muse, mutect2, varscan2
- GRPR | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1351631731, COSV66669848; called by muse, mutect2, varscan2
- GRWD1 | c.145A>G p.M49V | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.101); catalogued as rs1231757801, COSV53518429; called by muse, mutect2, varscan2
- GUCY2C | c.2177dup p.N726Kfs*17 | Frame Shift Ins (INS) | VAF 56/349 reads (16%) | catalogued as rs772079572; called by pindel, varscan2
- HAGHL | c.640del p.E214Rfs*15 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs747918697; called by mutect2, varscan2
- HAP1 | c.1278C>T p.S426= | Splice Region (SNP) | VAF 23/85 reads (27%) | catalogued as rs782764313, COSV100169843; called by muse, mutect2, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HELZ | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as COSV62377697; called by muse, mutect2, varscan2
- HERC2 | c.6035C>A p.P2012Q | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV55318891; called by muse, mutect2, varscan2
- HESX1 | c.533del p.N178Ifs*10 | Frame Shift Del (DEL) | VAF 201/722 reads (28%) | catalogued as rs759180706; called by mutect2, varscan2
- HFM1 | c.1331A>C p.N444T | Missense Mutation (SNP) | VAF 140/495 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV54025714; called by muse, mutect2, varscan2
- HIVEP1 | c.3786G>A p.W1262* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV65100564; called by muse, varscan2
- HIVEP3 | c.1601dup p.V535Cfs*26 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | catalogued as rs748174813; called by mutect2, varscan2
- HLA-DMB | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 71/282 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.244); catalogued as COSV66870670; called by muse, mutect2, varscan2
- HMCN1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV54893186; called by muse, mutect2, varscan2
- HMGCS2 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 114/383 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs61729865, COSV65567722; called by muse, mutect2, varscan2
- HOOK1 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV64618492; called by muse, mutect2, varscan2
- HPCAL4 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as COSV65716192; called by muse, mutect2, varscan2
- HRNR | c.5740G>A p.G1914R | Missense Mutation (SNP) | VAF 68/710 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.093); catalogued as rs751236412, COSV64260517; called by muse, mutect2
- HS3ST1 | c.635T>C p.I212T | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50023360; called by muse, mutect2, varscan2
- HTR1B | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64051364; called by muse, mutect2, varscan2
- HTR1E | c.646A>G p.R216G | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV59507695; called by muse, mutect2, varscan2
- HUS1 | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51839206; called by muse, mutect2, varscan2
- HUWE1 | c.10327A>G p.I3443V | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.456); catalogued as COSV53342336; called by muse, mutect2, varscan2
- HYAL1 | c.943dup p.A315Gfs*69 | Frame Shift Ins (INS) | VAF 14/73 reads (19%) | catalogued as rs1553712751; called by mutect2, pindel, varscan2
- IGF1R | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs761469469, COSV51279880; called by muse, mutect2, varscan2
- IGFALS | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51905444; called by muse, mutect2, varscan2
- IGFLR1 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV53074512; called by muse, mutect2, varscan2
- IGKV1D-16 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 132/516 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as rs368487539; called by muse, varscan2
- IGSF22 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV60033048; called by muse, varscan2
- IGSF9B | c.439dup p.Q147Pfs*10 | Frame Shift Ins (INS) | VAF 26/129 reads (20%) | catalogued as rs748943611; called by mutect2, varscan2
- IL10RB | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs776256199, COSV51614991; called by muse, mutect2, varscan2
- IL21R | c.1079del p.G360Afs*20 | Frame Shift Del (DEL) | VAF 28/130 reads (22%) | catalogued as COSV61969550; called by mutect2, pindel, varscan2
- IMPG2 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV51976689; called by muse, mutect2, varscan2
- ING5 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as rs375367616; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 158/281 reads (56%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IPO5 | c.319A>G p.K107E | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV55153906; called by muse, mutect2, varscan2
- IRAG1 | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 117/352 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101351043, COSV70212096; called by muse, mutect2, varscan2
- IRF1 | c.718-2A>G p.X240_splice | Splice Site (SNP) | VAF 40/138 reads (29%) | catalogued as COSV55377017; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs761880048; called by mutect2, varscan2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 54/106 reads (51%) | catalogued as rs780982673; called by mutect2, varscan2
- ISG20L2 | c.1016A>G p.E339G | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57460078; called by muse, mutect2, varscan2
- ITGA7 | c.1558C>A p.H520N (on ENST00000555728; = p.H476N on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV57694162; called by muse, mutect2, varscan2
- ITGAD | c.1273del p.R425Afs*50 | Frame Shift Del (DEL) | VAF 75/356 reads (21%) | catalogued as rs746237579, COSV66756833; called by mutect2, pindel, varscan2
- ITGB4 | c.5200A>G p.I1734V | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52324647; called by muse, mutect2, varscan2
- ITGB8 | c.27dup p.T10Yfs*34 | Frame Shift Ins (INS) | VAF 30/114 reads (26%) | catalogued as rs760028800; called by mutect2, varscan2
- ITPR3 | c.4675G>A p.A1559T | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV65408050; called by muse, mutect2
- JMJD7-PLA2G4B | c.1044+1G>A p.X348_splice | Splice Site (SNP) | VAF 29/119 reads (24%) | catalogued as COSV59823467; called by muse, mutect2, varscan2
- JUP | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60277678; called by muse, mutect2, varscan2
- KANK4 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100587657, COSV62986271; called by muse, mutect2, varscan2
- KARS1 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56691688; called by muse, mutect2, varscan2
- KAT7 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs769376467, COSV52014050; called by muse, mutect2, varscan2
- KATNA1 | c.769C>A p.L257I | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV59502132; called by muse, mutect2, varscan2
- KCNA5 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV52905131, COSV52905677; called by muse, mutect2, varscan2
- KCNC3 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763587981, COSV65387188, COSV65388186; called by muse, mutect2
- KCNH3 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57790374; called by muse, mutect2, varscan2
- KCNH5 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59752371; called by muse, mutect2, varscan2
- KCNJ10 | c.341C>G p.T114R | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV63633357; called by muse, mutect2, varscan2
- KCNJ12 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs112346542, COSV59165865; called by muse, mutect2, varscan2
- KCNJ12 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs140886918, COSV59167868; called by muse, mutect2, varscan2
- KCNQ5 | c.1036C>A p.L346I | Missense Mutation (SNP) | VAF 69/285 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59657158; called by muse, mutect2, varscan2
- KCNS1 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV60259953; called by muse, mutect2, varscan2
- KCTD1 | c.112G>C p.G38R | Missense Mutation (SNP) | VAF 279/533 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58685359; called by muse, mutect2, varscan2
- KCTD18 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 78/346 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774628683, COSV63344197; called by muse, mutect2, varscan2
- KCTD6 | c.133dup p.D45Gfs*15 | Frame Shift Ins (INS) | VAF 68/249 reads (27%) | catalogued as rs1381956518; called by mutect2, varscan2
- KDM1B | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as COSV52810063; called by muse, mutect2, varscan2
- KDM6B | c.2950C>T p.R984W | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.535); catalogued as rs1426663523, COSV54680412; called by muse, mutect2, varscan2
- KHDRBS2 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV55444471; called by muse, mutect2, varscan2
- KHSRP | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1053904540, COSV67919587; called by muse, mutect2, varscan2
- KIAA1217 | c.463del p.D155Mfs*19 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | catalogued as rs1264299382; called by mutect2, pindel, varscan2
- KIAA1549L | c.5418G>C p.Q1806H (on ENST00000321505; = p.Q2103H on NM_012194.3) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58586216; called by muse, mutect2
- KIAA1614 | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as COSV62552718; called by muse, mutect2, varscan2
- KIF15 | c.1696G>T p.G566* | Nonsense Mutation (SNP) | VAF 94/390 reads (24%) | catalogued as COSV100392959; called by muse, varscan2
- KIF17 | c.1400G>T p.G467V | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as COSV56117562; called by muse, mutect2
- KIF23 | c.2438G>A p.R813H (on ENST00000260363; = p.R709H on NM_004856.7) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs191196584; called by muse, mutect2, varscan2
- KIR2DL4 | c.601del p.E201Kfs*83 (on ENST00000396284; = p.E162Kfs*78 on NM_001080770.2) | Frame Shift Del (DEL) | VAF 30/126 reads (24%) | catalogued as rs1264603142; called by pindel, varscan2
- KLC4 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs372388180; called by muse, mutect2, varscan2
- KLF13 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56147373; called by muse, mutect2, varscan2
- KLHL10 | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs782416724, COSV99509565; called by muse, mutect2
- KLHL22 | c.1278G>A p.W426* | Nonsense Mutation (SNP) | VAF 22/99 reads (22%) | catalogued as rs1402905144, COSV61020567; called by muse, mutect2, varscan2
- KLHL25 | c.560G>A p.S187N | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV61994817; called by muse, mutect2, varscan2
- KLHL32 | c.953C>A p.A318D | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV65111627; called by muse, mutect2, varscan2
- KMT2B | c.5317C>T p.R1773C | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55859813; called by muse, mutect2, varscan2
- KNDC1 | c.3952C>T p.R1318W | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764482590, COSV58835210; called by muse, mutect2, varscan2
- KPNA5 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV62652019; called by muse, mutect2, varscan2
- KRT33A | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 74/251 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as rs746529701, COSV50365651; called by muse, mutect2, varscan2
- KRT72 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.698); catalogued as rs141162784; called by muse, mutect2, varscan2
- KRTAP19-5 | c.80G>T p.C27F | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV61858541; called by muse, mutect2, varscan2
- KRTCAP2 | c.389A>G p.H130R (on ENST00000497317; = p.T129A on NM_173852.4) | Missense Mutation (SNP) | VAF 116/411 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV55278631; called by muse, mutect2, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 42/133 reads (32%) | catalogued as rs750491454; called by mutect2, varscan2
- LACTB2 | c.309dup p.L104Tfs*28 | Frame Shift Ins (INS) | VAF 51/249 reads (20%) | catalogued as rs773915769; called by mutect2, pindel, varscan2
- LAMB1 | c.5125del p.T1709Lfs*22 | Frame Shift Del (DEL) | VAF 77/325 reads (24%) | catalogued as rs1441388757; called by mutect2, pindel, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 63/204 reads (31%) | catalogued as COSV60222740; called by mutect2, varscan2
- LARS1 | c.2173C>T p.L725F (on ENST00000394434 / NM_020117.11; = p.L698F on NM_016460.3) | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV50974351; called by muse, mutect2, varscan2
- LAT2 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs781903165, COSV51920641; called by muse, mutect2, varscan2
- LCP1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs755322384, COSV59940540; called by muse, mutect2, varscan2
- LGR4 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs760715826, COSV64864024; called by muse, mutect2, varscan2
- LHB | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs776040203, COSV55484878; called by muse, mutect2
- LILRA4 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV52491573; called by muse, mutect2, varscan2
- LMX1A | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as rs778377042, COSV54218498, COSV54225933; called by muse, mutect2, varscan2
- LOX | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV50237321; called by muse, mutect2
- LOXL3 | c.1400C>A p.A467D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51206992; called by muse, mutect2, varscan2
- LPL | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.678); catalogued as rs1185801397, COSV60930887; called by muse, mutect2, varscan2
- LRP8 | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1167089894, COSV100036646; called by muse, varscan2
- LRRC14B | c.765del p.T256Pfs*36 | Frame Shift Del (DEL) | VAF 110/471 reads (23%) | catalogued as rs748566980; called by mutect2, pindel, varscan2
- LRRC2 | c.980G>A p.G327D | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1470357473, COSV56125718; called by muse, mutect2, varscan2
- LRRC4C | c.741del p.K247Nfs*4 | Frame Shift Del (DEL) | VAF 45/177 reads (25%) | catalogued as COSV53426240; called by mutect2, pindel, varscan2
- LRRC56 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs201453048, COSV54240135; called by muse, mutect2
- LRRIQ4 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as rs754713329, COSV61618981; called by muse, mutect2, varscan2
- LRRN1 | c.1309G>A p.V437M | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as rs778235363, COSV60013467; called by muse, mutect2, varscan2
- LRRTM1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV54440253; called by muse, mutect2, varscan2
- LSM1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 124/317 reads (39%) | catalogued as COSV60948890; called by muse, mutect2, varscan2
- LZTR1 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs776112712, COSV53145563; called by muse, mutect2, varscan2
- MACF1 | c.18606G>T p.E6202D (on ENST00000372915; = p.E4247D on NM_012090.5) | Missense Mutation (SNP) | VAF 19/105 reads (18%) | catalogued as COSV57117464, COSV99245923; called by muse, mutect2, varscan2
- MAF | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs759815012, COSV58153689; called by muse, mutect2, varscan2
- MAGEE2 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs774700498, COSV64897174; called by muse, mutect2, varscan2
- MAK | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 19/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100504492; called by muse, mutect2
- MAMSTR | c.485dup p.H163Tfs*9 (on ENST00000318083 / NM_001130915.2; = p.H60Tfs*9 on NM_182574.2) | Frame Shift Ins (INS) | VAF 26/143 reads (18%) | catalogued as rs752869239; called by mutect2, varscan2
- MAP3K19 | c.3469C>T p.P1157S | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs372912449; called by muse, mutect2, varscan2
- MAP4K4 | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV56329592; called by muse, mutect2, varscan2
- MAP6 | c.2438C>A p.P813H | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV59075241; called by muse, mutect2, varscan2
- MAPK10 | c.845C>T p.A282V (on ENST00000359221 / NM_001351625.2; = p.A320V on NM_002753.5) | Missense Mutation (SNP) | VAF 123/504 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs757125320, COSV60380345; called by muse, mutect2, varscan2
- MARF1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.98); catalogued as rs748092725, COSV60022346; called by muse, mutect2, varscan2
- MAST2 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 44/327 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1324682611, COSV63616128; called by muse, mutect2, varscan2
- MAST4 | c.1412A>C p.K471T (on ENST00000403625 / NM_001164664.2; = p.K282T on NM_015183.3) | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55122140; called by muse, mutect2, varscan2
- MDGA1 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); catalogued as rs764209266, COSV51794703; called by muse, mutect2, varscan2
- MED12L | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.885); catalogued as rs571847223, COSV56370076; called by muse, mutect2, varscan2
- MEGF6 | c.4363C>T p.R1455C | Missense Mutation (SNP) | VAF 78/308 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs747814645, COSV53888635; called by muse, mutect2, varscan2
- MELTF | c.2003G>A p.G668D | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as COSV56380646; called by muse, mutect2, varscan2
- MESP2 | c.718del p.V240Sfs*241 | Frame Shift Del (DEL) | VAF 34/145 reads (23%) | catalogued as rs756232049; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- MFSD14B | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 120/510 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.221); catalogued as rs1309735022, COSV100942715; called by muse, varscan2
- MGAM | c.3725G>T p.W1242L | Missense Mutation (SNP) | VAF 114/364 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV72074456; called by muse, mutect2, varscan2
- MICU2 | c.271A>G p.M91V | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as COSV66673705; called by muse, mutect2, varscan2
- MIS18BP1 | c.1139del p.N380Ifs*3 | Frame Shift Del (DEL) | VAF 48/182 reads (26%) | catalogued as rs751180035; called by mutect2, varscan2
- MKS1 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs777558323, COSV58303491; ClinVar: uncertain significance; called by muse, varscan2
- MLPH | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as COSV52819627; called by muse, mutect2, varscan2
- MME | c.160+1G>A p.X54_splice | Splice Site (SNP) | VAF 38/120 reads (32%) | catalogued as COSV64706912; called by muse, mutect2, varscan2
- MMP16 | c.251T>A p.M84K | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV54160437; called by muse, mutect2, varscan2
- MN1 | c.129del p.P45Lfs*8 | Frame Shift Del (DEL) | VAF 43/175 reads (25%) | catalogued as COSV56556167; called by mutect2, pindel, varscan2
- MPHOSPH8 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); catalogued as rs1437386376, COSV64055199; called by muse, mutect2, varscan2
- MPRIP | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV59047078; called by muse, mutect2, varscan2
- MSANTD4 | c.33T>G p.N11K | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57285644; called by muse, mutect2, varscan2
- MSL3 | c.867A>T p.K289N (on ENST00000312196 / NM_078629.4; = p.K123N on NM_006800.4) | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV56492572, COSV56495105; called by muse, mutect2, varscan2
- MTA2 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1302534267, COSV53871066; called by muse, mutect2, varscan2
- MTMR7 | c.1948C>T p.R650W | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1159639189, COSV51665132; called by muse, mutect2, varscan2
- MTMR9 | c.584dup p.N195Kfs*41 | Frame Shift Ins (INS) | VAF 27/156 reads (17%) | catalogued as rs767880823; called by mutect2, varscan2
- MUC16 | c.40516A>G p.T13506A | Missense Mutation (SNP) | VAF 81/268 reads (30%) | SIFT tolerated, low confidence (0.55); PolyPhen probably damaging (0.953); catalogued as COSV66691246; called by muse, mutect2, varscan2
- MUC16 | c.35554A>C p.T11852P | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV67459990; called by muse, mutect2, varscan2
- MUC5B | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs559689592, COSV71591348; called by muse, mutect2, varscan2
- MYBBP1A | c.3202C>T p.R1068C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs573540438, COSV54596667; called by muse, mutect2, varscan2
- MYCBP2 | c.7029T>A p.N2343K (on ENST00000357337; = p.N2381K on NM_015057.5) | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV62015562, COSV62039777; called by muse, mutect2, varscan2
- MYCBP2 | c.1817C>T p.A606V (on ENST00000357337; = p.A644V on NM_015057.5) | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62015588; called by muse, mutect2, varscan2
- MYCBP2 | c.215A>G p.K72R (on ENST00000357337; = p.K110R on NM_015057.5) | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV62015607; called by muse, mutect2
- MYCBPAP | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.173); catalogued as COSV60406826; called by muse, mutect2, varscan2
- MYH14 | c.4886G>A p.R1629H | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759824498, COSV51815031; called by muse, mutect2, varscan2
- MYH4 | c.3353G>A p.R1118H | Missense Mutation (SNP) | VAF 83/313 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1248088400, COSV55116420; called by muse, mutect2, varscan2
- MYH9 | c.869-1G>A p.X290_splice | Splice Site (SNP) | VAF 27/111 reads (24%) | catalogued as COSV53384961; called by muse, mutect2, varscan2
- MYL2 | c.172C>A p.R58= | Splice Region (SNP) | VAF 21/119 reads (18%) | catalogued as rs756671869, CM1411019, COSV57406779, COSV99960732; called by muse, varscan2
- MYL4 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); catalogued as rs1050214578, COSV61698176; called by muse, mutect2
- MYLK4 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759016773, COSV51139935; called by muse, mutect2, varscan2
- NAGK | c.959C>A p.A320D | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54903368; called by muse, mutect2, varscan2
- NAT8L | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 66/254 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.03); catalogued as rs748667405, COSV59051075; called by muse, mutect2, varscan2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 33/94 reads (35%) | catalogued as rs763376147; called by mutect2, varscan2
- NBEAL2 | c.991A>G p.N331D | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as COSV52756587; called by muse, mutect2, varscan2
- NCAPH2 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs751567124, COSV52687399; called by muse, mutect2, varscan2
- NCOA2 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745580019, COSV71763510; called by muse, mutect2, varscan2
- NCOR1 | c.5366C>A p.P1789Q | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV51971108; called by muse, mutect2, varscan2
- NDUFA9 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.271); catalogued as rs772426441, COSV56927763; called by muse, mutect2, varscan2
- NEFL | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.05); catalogued as rs558065942, COSV55336778; called by muse, mutect2
- NEO1 | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as rs766139025, COSV56070071; called by muse, mutect2, varscan2
- NFASC | c.451G>A p.V151M (on ENST00000339876 / NM_001378329.1; = p.V145M on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.419); catalogued as rs768892415, COSV58363683; called by muse, varscan2
- NFX1 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 48/391 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV59309603; called by muse, mutect2, varscan2
- NHLRC3 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs1201614065, COSV101098990; called by muse, varscan2
- NIPSNAP1 | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53342362; called by muse, mutect2, varscan2
- NISCH | c.3977G>T p.G1326V | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58734931; called by muse, varscan2
- NLRC5 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317479911, COSV52653486; called by muse, mutect2, varscan2
- NLRC5 | c.4323-1G>T p.X1441_splice | Splice Site (SNP) | VAF 83/289 reads (29%) | catalogued as COSV52653521; called by muse, mutect2, varscan2
- NOBOX | c.1322del p.P441Hfs*25 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as rs753934412; called by mutect2, pindel, varscan2
- NOD2 | c.1583del p.P528Qfs*235 | Frame Shift Del (DEL) | VAF 29/116 reads (25%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOP9 | c.1607_1608del p.V536Dfs*22 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | catalogued as rs764970211; called by pindel, varscan2
- NOS1 | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV57610616; called by muse, mutect2
- NOX5 | c.1302G>T p.K434N | Missense Mutation (SNP) | VAF 86/350 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52987547; called by muse, mutect2, varscan2
- NPDC1 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs564238459, COSV58663976; called by muse, mutect2, varscan2
- NPR1 | c.1818del p.N607Ifs*62 | Frame Shift Del (DEL) | VAF 69/237 reads (29%) | catalogued as rs772189906; called by mutect2, pindel, varscan2
- NR4A2 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.339); catalogued as COSV59893408; called by muse, mutect2, varscan2
- NR5A2 | c.1316G>A p.R439H (on ENST00000367362 / NM_205860.3; = p.R393H on NM_003822.5) | Missense Mutation (SNP) | VAF 117/532 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.112); catalogued as rs1182541887, COSV52648273, COSV52648662; called by muse, mutect2, varscan2
- NRXN2 | c.3685C>T p.R1229C | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55447324; called by muse, mutect2, varscan2
- NSD1 | c.6738G>T p.Q2246H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV61774819; called by muse, mutect2, varscan2
- NSG2 | c.309G>T p.E103D | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57457548; called by muse, mutect2, varscan2
- NUGGC | c.541A>T p.R181* | Nonsense Mutation (SNP) | VAF 106/456 reads (23%) | catalogued as COSV58434052; called by muse, mutect2, varscan2
- NUP107 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.125); catalogued as rs879229784, COSV99971858; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 48/209 reads (23%) | catalogued as rs780417788; called by mutect2, varscan2
- OGDH | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56048404; called by muse, mutect2, varscan2
- OLAH | c.489del p.K164Sfs*10 (on ENST00000378228 / NM_001039702.3; = p.K217Sfs*10 on NM_018324.3) | Frame Shift Del (DEL) | VAF 58/213 reads (27%) | catalogued as rs774581354; called by mutect2, pindel, varscan2
- OPLAH | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs905023926, COSV70677780; called by muse, mutect2, varscan2
- OR13J1 | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.102); catalogued as rs369145177; called by muse, mutect2, varscan2
- OR2A5 | c.786del p.K263Sfs*23 | Frame Shift Del (DEL) | VAF 78/314 reads (25%) | catalogued as COSV68738799; called by mutect2, pindel, varscan2
- OR2S2 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV59529838; called by muse, mutect2, varscan2
- OR4A15 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 83/328 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); catalogued as rs1423687925, COSV59033796, COSV59035039; called by muse, mutect2, varscan2
- OR4C15 | c.950C>A p.A317D (on ENST00000314644; = p.A263D on NM_001001920.2) | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.085); catalogued as rs768461616, COSV58952258; called by muse, mutect2, varscan2
- OR4X2 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 104/375 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV56583033; called by muse, varscan2
- OR52I1 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 61/223 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758198757, COSV56168215; called by muse, mutect2, varscan2
- OR52R1 | c.193T>C p.F65L | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV61888120; called by muse, mutect2, varscan2
- OR5K2 | c.17A>G p.H6R | Missense Mutation (SNP) | VAF 71/420 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs765219693, COSV71143134; called by muse, mutect2, varscan2
- OR6X1 | c.371T>G p.I124S | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60009652; called by muse, mutect2, varscan2
- OTOA | c.1046A>G p.Y349C (on ENST00000286149; = p.Y335C on NM_144672.4) | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754830603, COSV53752422; called by muse, mutect2, varscan2
- OTOA | c.1777A>G p.M593V (on ENST00000286149; = p.M579V on NM_144672.4) | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV99625019; called by muse, mutect2, varscan2
- OTOGL | c.4163G>A p.S1388N (on ENST00000547103; = p.S1379N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV72006466; called by muse, mutect2, varscan2
- OTUD7A | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61035842; called by muse, mutect2, varscan2
- OXCT2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs774090598, COSV59593687; called by muse, mutect2, varscan2
- P2RX6 | c.1244C>A p.A415D | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV60383272; called by muse, mutect2, varscan2
- P2RY13 | c.702del p.V235Yfs*81 | Frame Shift Del (DEL) | VAF 46/247 reads (19%) | catalogued as rs771457469; called by mutect2, pindel, varscan2
- P2RY2 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as rs1241008063, COSV60775835; called by muse, mutect2, varscan2
- PANK1 | c.1199dup p.P401Afs*5 (on ENST00000307534 / NM_148977.2; = p.P176Afs*5 on NM_138316.4) | Frame Shift Ins (INS) | VAF 36/166 reads (22%) | catalogued as rs1564621823; called by mutect2, varscan2
- PAQR6 | c.952G>A p.A318T (on ENST00000292291 / NM_001272108.2; = p.Q235= on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52744906; called by muse, mutect2, varscan2
- PASK | c.3065del p.N1022Tfs*6 | Frame Shift Del (DEL) | VAF 37/140 reads (26%) | catalogued as rs745388191; called by mutect2, varscan2
- PCDH12 | c.919C>A p.R307S | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.41); catalogued as COSV51520832; called by muse, mutect2, varscan2
- PCDH15 | c.4749G>T p.R1583S | Missense Mutation (SNP) | VAF 84/339 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV100223027; called by muse, mutect2, varscan2
- PCDHA13 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 114/415 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs140457638; called by muse, mutect2, varscan2
- PCDHA6 | c.1286A>G p.D429G | Missense Mutation (SNP) | VAF 118/457 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV67046697; called by muse, mutect2, varscan2
- PCDHA9 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 66/252 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65324524; called by muse, mutect2, varscan2
- PCDHB7 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 86/319 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV50838059; called by muse, mutect2, varscan2
- PCDHGA4 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); catalogued as rs760842215, COSV53930460, COSV54016618; called by muse, mutect2, varscan2
- PCDHGB4 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53930479, COSV53943562; called by muse, mutect2, varscan2
- PCDHGB5 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs774561101, COSV53930506; called by muse, mutect2, varscan2
- PCLO | c.6787_6789del p.V2263del | In Frame Del (DEL) | VAF 17/100 reads (17%) | catalogued as rs779111466; called by mutect2, pindel, varscan2
- PDE4DIP | c.6053C>T p.A2018V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs782336046, COSV57690796; called by mutect2, varscan2
- PDGFRB | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as COSV55803659; called by muse, mutect2, varscan2
- PDK1 | c.1084T>C p.S362P | Missense Mutation (SNP) | VAF 129/461 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV56375028; called by muse, mutect2, varscan2
- PHC1 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs181118510, COSV70417735; called by muse, mutect2, varscan2
- PHC2 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs145654669; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as rs769717544; called by mutect2, varscan2
- PIK3R4 | c.3566G>A p.R1189H | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs776446334, COSV63240359; called by muse, mutect2, varscan2
- PITPNM2 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752872683, COSV54899347; called by muse, mutect2, varscan2
- PITPNM3 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV52594892; called by muse, mutect2, varscan2
- PKD1L1 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs764840801, COSV56962931, COSV99218294; called by muse, mutect2, varscan2
- PKD2L1 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV58395569; called by muse, mutect2, varscan2
- PKP4 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs550760431, COSV67676513; called by muse, mutect2, varscan2
- PLCB1 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 116/375 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs751256923, COSV62039592; called by muse, mutect2, varscan2
- PLCB3 | c.1266G>T p.Q422H | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54187702; called by muse, mutect2, varscan2
- PLEKHA6 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs761615025, COSV55332371; called by muse, mutect2, varscan2
- PLEKHM1 | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs1259240823, COSV101378788; called by muse, mutect2, varscan2
- PLEKHO2 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.178); catalogued as COSV60261872; called by muse, mutect2, varscan2
- PLPPR4 | c.970T>G p.L324V | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as COSV64565380; called by muse, mutect2, varscan2
- PLSCR5 | c.784A>G p.M262V | Missense Mutation (SNP) | VAF 131/799 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV71649008; called by muse, mutect2, varscan2
- PLXNA2 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1410296684, COSV65439866; called by muse, mutect2, varscan2
- PLXNA3 | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs376086499, COSV63753818; called by muse, mutect2, varscan2
- PLXNA4 | c.4589A>G p.E1530G | Missense Mutation (SNP) | VAF 74/235 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58118409; called by muse, mutect2, varscan2
- PLXNC1 | c.1062C>T p.C354= | Splice Region (SNP) | VAF 10/66 reads (15%) | catalogued as COSV99313389; called by muse, mutect2
- POLD2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs768064825, COSV99788899; called by muse, mutect2, varscan2
- POLR3D | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV60570959; called by muse, mutect2, varscan2
- PPAT | c.1298C>A p.P433H | Missense Mutation (SNP) | VAF 95/377 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51703765; called by muse, mutect2, varscan2
- PPIE | c.53A>G p.D18G | Missense Mutation (SNP) | VAF 89/249 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV60971234; called by muse, mutect2, varscan2
- PPP1R8 | c.802C>T p.P268S (on ENST00000311772 / NM_014110.5; = p.P44S on NM_002713.4) | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); catalogued as rs1489281256, COSV52579842; called by muse, mutect2, varscan2
- PPP2R2B | c.518C>T p.T173I (on ENST00000394409; = p.T239I on NM_181674.2) | Missense Mutation (SNP) | VAF 43/385 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100355180; called by muse, mutect2, varscan2
- PPP2R3B | c.1408A>G p.T470A | Missense Mutation (SNP) | VAF 113/334 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.224); catalogued as COSV66813089; called by muse, varscan2
- PPP6R2 | c.552C>T p.H184= | Splice Region (SNP) | VAF 24/80 reads (30%) | catalogued as rs544160556, COSV53292218; called by muse, varscan2
- PPP6R2 | c.2720G>T p.S907I (on ENST00000216061 / NM_001365836.1; = p.S873I on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.207); catalogued as COSV53292241; called by muse, mutect2, varscan2
- PPRC1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs771663512, COSV53383276; called by muse, mutect2, varscan2
- PREX1 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as rs765882639, COSV64250654; called by muse, varscan2
- PRKAR2B | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs76105568, COSV99708384; called by muse, mutect2, varscan2
- PRKD1 | c.1796G>T p.G599V | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV59565492, COSV59579251; called by muse, mutect2, varscan2
- PROC | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1343264503, CM005574, CM951015, COSV52165433; called by muse, mutect2, varscan2
- PROKR1 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs773486402, COSV58137233; called by muse, mutect2, varscan2
- PRPF38B | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 49/197 reads (25%) | catalogued as rs775081443, COSV100898294; called by muse, mutect2, varscan2
- PRPF4 | c.1372+1G>A p.X458_splice (on ENST00000374198 / NM_001322267.2; = p.X459_splice on NM_004697.5) | Splice Site (SNP) | VAF 68/179 reads (38%) | catalogued as rs1443418385, COSV65252536; called by muse, mutect2, varscan2
- PRRT3 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55976919; called by muse, mutect2, varscan2
- PSD4 | c.40A>G p.M14V | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55525922; called by muse, mutect2, varscan2
- PSMC3 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 84/344 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV54080729; called by muse, mutect2, varscan2
- PSPC1 | c.1267G>A p.G423S | Missense Mutation (SNP) | VAF 56/835 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs776499795, COSV100142225, COSV100142429; called by muse, mutect2
- PTCH1 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59470600, COSV59473699; called by muse, mutect2, varscan2
- PTK2B | c.2709del p.E904Rfs*7 | Frame Shift Del (DEL) | VAF 29/155 reads (19%) | catalogued as rs869044240; called by mutect2, pindel, varscan2
- PTPN1 | c.136T>C p.Y46H | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV63298682; called by muse, mutect2, varscan2
- PTPN13 | c.2770C>T p.P924S | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.94); catalogued as rs763863340, COSV57405904; called by muse, mutect2, varscan2
- PTPRH | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 122/427 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs750050374, COSV54744538; called by muse, mutect2, varscan2
- PTPRM | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100159959, COSV59854513; called by muse, mutect2, varscan2
- PTPRS | c.1239del p.S414Afs*30 | Frame Shift Del (DEL) | VAF 33/121 reads (27%) | catalogued as rs1390768500; called by mutect2, pindel
- PTPRT | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.527); catalogued as rs776769442, COSV61975097; called by muse, mutect2, varscan2
- PTX4 | c.1191del p.G398Efs*57 (on ENST00000447419 / NM_001328608.2; = p.G393Efs*57 on NM_001013658.1) | Frame Shift Del (DEL) | VAF 30/93 reads (32%) | catalogued as rs772722517, COSV99560265; called by mutect2, varscan2
- PYHIN1 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV63722102; called by muse, mutect2, varscan2
- PYY | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV63970287; called by muse, mutect2, varscan2
- PYY | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 64/226 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs754534017, COSV63970296; called by muse, mutect2, varscan2
- R3HDM1 | c.409T>G p.L137V | Missense Mutation (SNP) | VAF 116/499 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51523412; called by muse, mutect2, varscan2
- RAB6A | c.440A>C p.E147A | Missense Mutation (SNP) | VAF 68/306 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV60178136, COSV60180710; called by muse, mutect2, varscan2
- RANBP2 | c.3521C>T p.P1174L | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51699540; called by muse, mutect2, varscan2
- RARG | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as rs769476878, COSV58432531; ClinVar: likely benign; called by muse, mutect2, varscan2
- RASA1 | c.1600C>A p.L534I | Missense Mutation (SNP) | VAF 89/305 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV57194536; called by muse, mutect2, varscan2
- RB1CC1 | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs753833588, COSV50246200; called by muse, mutect2, varscan2
- RBBP6 | c.3355A>G p.K1119E | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); catalogued as COSV60504491; called by muse, mutect2, varscan2
- RBBP8NL | c.314-1G>A p.X105_splice | Splice Site (SNP) | VAF 21/78 reads (27%) | catalogued as COSV53348846; called by muse, mutect2, varscan2
- RBBP9 | c.313del p.D105Mfs*70 | Frame Shift Del (DEL) | VAF 99/407 reads (24%) | catalogued as rs755841243; called by mutect2, pindel, varscan2
- RBM12 | c.2450G>A p.G817E | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.44); catalogued as COSV58290818; called by muse, mutect2, varscan2
- RBMS1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 75/314 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV62352428; called by muse, mutect2, varscan2
- RBPMS | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 19/92 reads (21%) | catalogued as COSV55122363; called by muse, mutect2, varscan2
- RELL1 | c.307A>G p.K103E | Missense Mutation (SNP) | VAF 86/340 reads (25%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.982); catalogued as COSV58451150; called by muse, varscan2
- RELN | c.2887G>A p.V963I | Missense Mutation (SNP) | VAF 105/384 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as rs761991712, COSV58996805; called by muse, varscan2
- RELN | c.2737C>T p.R913C | Missense Mutation (SNP) | VAF 68/298 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771172788, COSV58996814; ClinVar: uncertain significance; called by muse, varscan2
- REST | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 88/377 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV58360185; called by muse, mutect2, varscan2
- RET | c.864G>T p.K288N | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV60691798; called by muse, varscan2
- RFX7 | c.4069C>T p.P1357S (on ENST00000559447 / NM_001368074.1; = p.P1454S on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as COSV57962275; called by muse, mutect2, varscan2
- RGS22 | c.3611G>A p.R1204Q | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs760451465, COSV62660533, COSV62662536; called by muse, mutect2, varscan2
- RGS3 | c.3080+1G>A p.X1027_splice (on ENST00000350696 / NM_001282923.2; = p.X746_splice on NM_130795.4) | Splice Site (SNP) | VAF 34/162 reads (21%) | catalogued as rs771706809, COSV59514993; called by muse, mutect2, varscan2
- RGS7 | c.40del p.V14Wfs*18 | Frame Shift Del (DEL) | VAF 34/142 reads (24%) | catalogued as COSV100777167; called by pindel, varscan2
- RHBDD1 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1474029910, COSV58125509; called by muse, mutect2, varscan2
- RHBG | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 61/239 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as rs371854390; called by muse, mutect2, varscan2
- RIMS1 | c.370T>C p.F124L | Missense Mutation (SNP) | VAF 59/346 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53451025; called by muse, mutect2, varscan2
- RINL | c.1523A>C p.H508P (on ENST00000591812 / NM_001195833.2; = p.H394P on NM_198445.4) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61574492; called by muse, mutect2, varscan2
- RLN2 | c.20del p.F7Sfs*4 | Frame Shift Del (DEL) | VAF 90/330 reads (27%) | catalogued as rs760343057; called by mutect2, varscan2
- RND3 | c.228G>T p.W76C | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV55724111; called by muse, varscan2
- RNF123 | c.2845G>A p.A949T | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs368723431, COSV57538256; called by muse, mutect2, varscan2
- RNF152 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.024); catalogued as rs565129525, COSV57185003; called by muse, mutect2
- RNF213 | c.13940G>A p.R4647H | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs767758584, COSV60388624; called by muse, mutect2, varscan2
- RNF44 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1300897504, COSV51269542; called by muse, mutect2, varscan2
- RNH1 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as COSV100596779; called by muse, varscan2
- RNPEPL1 | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV54372379; called by muse, mutect2, varscan2
- RPL22 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 232/1196 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV52377904; called by muse, varscan2
- RPS6 | c.498T>C p.G166= | Splice Region (SNP) | VAF 15/56 reads (27%) | catalogued as COSV59547804; called by muse, mutect2, varscan2
- RTL5 | c.1582T>C p.S528P | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV101030192; called by muse, mutect2, varscan2
- RUFY1 | c.1872G>T p.M624I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.109); catalogued as COSV100106205; called by muse, varscan2
- RYR2 | c.1397del p.P466Qfs*5 | Frame Shift Del (DEL) | VAF 30/135 reads (22%) | catalogued as COSV100771204; called by mutect2, pindel, varscan2
- SAMD4B | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs774597687, COSV58751141; called by muse, mutect2, varscan2
- SAMD9L | c.4540A>G p.K1514E | Missense Mutation (SNP) | VAF 148/526 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.204); catalogued as rs773710761, COSV59080075, COSV59080638; called by muse, mutect2, varscan2
- SBNO1 | c.2140C>T p.R714* (on ENST00000420886; = p.R713* on NM_018183.5) | Nonsense Mutation (SNP) | VAF 117/404 reads (29%) | catalogued as COSV99031854; called by muse, mutect2, varscan2
- SBNO2 | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774717752, COSV62320029; called by muse, mutect2, varscan2
- SCFD2 | c.152del p.G51Vfs*27 | Frame Shift Del (DEL) | VAF 30/131 reads (23%) | catalogued as rs753794117; called by mutect2, pindel, varscan2
- SCGB3A2 | c.100T>G p.L34V | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57023231; called by muse, mutect2, varscan2
- SCIN | c.1410G>T p.Q470H (on ENST00000297029 / NM_001112706.3; = p.Q223H on NM_033128.3) | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51691716; called by muse, mutect2, varscan2
- SCN2B | c.503del p.G168Afs*10 | Frame Shift Del (DEL) | VAF 45/183 reads (25%) | catalogued as rs1565462817; called by mutect2, pindel, varscan2
- SCN3A | c.2345A>G p.Y782C | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51807379; called by muse, mutect2, varscan2
- SCTR | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV50027528; called by muse, mutect2, varscan2
- SCUBE1 | c.1890C>T p.C630= | Splice Region (SNP) | VAF 15/66 reads (23%) | catalogued as rs570310016, COSV62611708; called by muse, mutect2, varscan2
- SEC62 | c.429del p.D144Mfs*58 | Frame Shift Del (DEL) | VAF 66/221 reads (30%) | catalogued as rs751191303; called by mutect2, varscan2
- SEMA3C | c.968G>A p.G323D | Missense Mutation (SNP) | VAF 95/376 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54844801; called by muse, mutect2, varscan2
- SEMA6C | c.2701G>A p.D901N | Missense Mutation (SNP) | VAF 73/262 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.174); catalogued as COSV59002020; called by muse, mutect2, varscan2
- SERPINB6 | c.787-1G>T p.X263_splice (on ENST00000612421 / NM_001271823.2; = p.X244_splice on NM_004568.6) | Splice Site (SNP) | VAF 40/162 reads (25%) | catalogued as rs1223476137, CS1513073, COSV59565529; called by muse, mutect2, varscan2
- SERPINB8 | c.61del p.E21Kfs*13 | Frame Shift Del (DEL) | VAF 67/148 reads (45%) | catalogued as rs1568270721; called by mutect2, pindel, varscan2
- SETD1A | c.4372G>T p.D1458Y | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV52686821; called by muse, mutect2, varscan2
- SFMBT2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760397823, COSV62808284; called by muse, mutect2, varscan2
- SFXN2 | c.917A>G p.K306R | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV64012032; called by muse, mutect2, varscan2
- SGSM1 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV68509900; called by muse, mutect2, varscan2
- SH3BP4 | c.2414T>A p.L805Q | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60643542; called by muse, mutect2, varscan2
- SHB | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.661); catalogued as rs550122136, COSV66628921; called by muse, mutect2, varscan2
- SHFL | c.566del p.P189Rfs*67 | Frame Shift Del (DEL) | VAF 34/108 reads (31%) | catalogued as COSV53462966; called by mutect2, varscan2
- SIGLEC11 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1362564120, COSV70221955; called by muse, mutect2, varscan2
- SKA1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs375685203; called by muse, mutect2
- SLC12A3 | c.2000G>A p.R667Q | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs753341636, COSV52632627; called by muse, mutect2, varscan2
- SLC13A2 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100120383; called by muse, varscan2
- SLC13A3 | c.1392del p.A465Pfs*38 | Frame Shift Del (DEL) | VAF 18/109 reads (17%) | catalogued as rs780410569; called by pindel, varscan2
- SLC13A3 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51714510; called by muse, mutect2, varscan2
- SLC15A3 | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs138688557; called by muse, mutect2, varscan2
- SLC1A7 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65195020; called by muse, mutect2, varscan2
- SLC24A2 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53862812; called by muse, mutect2, varscan2
- SLC25A19 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372219499, COSV57467467; called by muse, mutect2, varscan2
- SLC25A2 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as COSV53403520; called by muse, mutect2, varscan2
- SLC28A2 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 150/544 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61663768; called by muse, mutect2, varscan2
- SLC2A4 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99142753; called by muse, mutect2, varscan2
- SLC30A8 | c.215G>A p.W72* | Nonsense Mutation (SNP) | VAF 20/123 reads (16%) | catalogued as COSV69968385; called by muse, mutect2, varscan2
- SLC30A9 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156285599, COSV52555395; called by muse, mutect2, varscan2
- SLC38A3 | c.1220A>G p.H407R | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68843959; called by muse, mutect2, varscan2
- SLC4A1 | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 72/263 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV52259457; called by muse, mutect2, varscan2
- SLC51A | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV53057162; called by muse, mutect2, varscan2
- SLC6A11 | c.608T>A p.V203D | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV54392440; called by muse, mutect2, varscan2
- SLC9C1 | c.2014del p.S672Hfs*9 | Frame Shift Del (DEL) | VAF 55/266 reads (21%) | catalogued as rs761139813; called by mutect2, pindel, varscan2
- SLCO4C1 | c.129T>G p.N43K | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV60514840; called by muse, mutect2, varscan2
- SLIT1 | c.2137G>A p.A713T | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56587274; called by muse, mutect2, varscan2
- SLIT3 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs926590189, COSV60603476; called by muse, mutect2, varscan2
- SLITRK3 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV53847321, COSV53849415; called by muse, mutect2, varscan2
- SLITRK4 | c.1685C>T p.T562M | Missense Mutation (SNP) | VAF 72/133 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs149752985, COSV62023252; called by muse, mutect2, varscan2
- SLMAP | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs367733735; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCA2 | c.3466G>A p.A1156T | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM149464, COSV61806527; called by muse, mutect2, varscan2
- SMC1A | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs587784407, COSV59128773; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SMCHD1 | c.3015del p.D1006Tfs*39 | Frame Shift Del (DEL) | VAF 27/121 reads (22%) | catalogued as rs1568252824; called by mutect2, pindel, varscan2
- SMCR8 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.959); catalogued as rs200340935, COSV68810841; called by muse, mutect2, varscan2
- SMPD4 | c.1337C>T p.P446L (on ENST00000409031 / NM_017951.4; = p.P417L on NM_017751.4) | Missense Mutation (SNP) | VAF 81/374 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747433356, COSV60079770; called by muse, mutect2, varscan2
- SNRNP27 | c.383C>A p.A128D | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV54911425; called by muse, mutect2
- SNX1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56037962; called by muse, mutect2, varscan2
- SOGA3 | c.722del p.G241Afs*133 | Frame Shift Del (DEL) | VAF 43/185 reads (23%) | catalogued as rs778091058, COSV100846885; called by mutect2, pindel, varscan2
- SORL1 | c.5186G>A p.R1729H | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs534646732, COSV52751649; called by muse, mutect2, varscan2
- SPEN | c.2194C>T p.R732* | Nonsense Mutation (SNP) | VAF 33/124 reads (27%) | catalogued as rs751475729, COSV65361122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPNS1 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as rs750776330, COSV57954378; called by muse, mutect2, varscan2
- SPPL2B | c.1114A>T p.S372C | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV101194662; called by muse, mutect2, varscan2
- SPSB1 | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV60162895; called by muse, mutect2, varscan2
- SPTAN1 | c.7323C>G p.C2441W | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV63986545; called by muse, mutect2, varscan2
- SPTBN5 | c.7526T>C p.L2509S | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58019451; called by muse, mutect2, varscan2
- SREBF1 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs566513103, COSV55416056; called by muse, mutect2, varscan2
- SRFBP1 | c.454A>G p.N152D | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs1387131664, COSV59582503; called by muse, mutect2, varscan2
- SRSF7 | c.538A>G p.R180G | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.191); catalogued as rs776682235, COSV57446836; called by muse, varscan2
- SS18L1 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as rs1296903435, COSV59210054; called by muse, mutect2
- SSTR3 | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV60729128, COSV60729224; called by muse, mutect2, varscan2
- STARD8 | c.2723A>T p.H908L | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV52924945; called by muse, mutect2, varscan2
- STAT5A | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs575765283, COSV61806433; called by muse, mutect2, varscan2
- STAU1 | c.1580C>A p.P527Q (on ENST00000371856 / NM_001319135.1; = p.P446Q on NM_004602.3) | Missense Mutation (SNP) | VAF 112/454 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61459902; called by muse, mutect2, varscan2
- STK10 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1483520161, COSV51571290, COSV51573051; called by muse, mutect2, varscan2
- STRIP1 | c.2311C>A p.L771I | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV63930485; called by muse, mutect2, varscan2
- STXBP2 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs746897867, CM096292, COSV55402827; called by muse, mutect2, varscan2
- STXBP3 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750050452, COSV64181653; called by muse, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 43/194 reads (22%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYCE1 | c.902C>A p.A301D (on ENST00000343131 / NM_001143764.3; = p.A265D on NM_130784.3) | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV58216755; called by muse, mutect2, varscan2
- SYMPK | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV55610945; called by muse, mutect2, varscan2
- TACC1 | c.1021C>T p.L341F | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV52523261; called by muse, mutect2, varscan2
- TAS2R8 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53688614; called by muse, mutect2, varscan2
- TC2N | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV100562976; called by muse, mutect2
- TCERG1 | c.2203dup p.M735Nfs*8 | Frame Shift Ins (INS) | VAF 194/772 reads (25%) | catalogued as rs1402716842; called by mutect2, varscan2
- TCF25 | c.1988C>T p.A663V | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs558866331, COSV54526557; called by muse, mutect2, varscan2
- TDRP | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs759540788, COSV60705480; called by muse, mutect2, varscan2
- TECTA | c.2134G>A p.V712M | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as rs876657587, COSV50700879; called by muse, mutect2, varscan2
- TEKT5 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs774554761, COSV51588035; called by muse, mutect2
- TENM1 | c.6070C>T p.R2024C | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64427330; called by muse, mutect2, varscan2
- TENM1 | c.41A>G p.K14R | Missense Mutation (SNP) | VAF 135/259 reads (52%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.992); catalogued as COSV64430056; called by muse, mutect2, varscan2
- TET3 | c.5243dup p.T1749Hfs*5 | Frame Shift Ins (INS) | VAF 46/174 reads (26%) | catalogued as rs759623160; called by mutect2, varscan2
- TEX15 | c.6053T>A p.L2018* (on ENST00000256246; = p.L2401* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 35/151 reads (23%) | catalogued as rs1408196762, COSV56345055; called by muse, mutect2, varscan2
- TGM2 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751214792, COSV63931357; called by muse, mutect2, varscan2
- THAP9 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 89/388 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as COSV56356156; called by muse, mutect2, varscan2
- TLCD5 | c.148C>A p.L50I (on ENST00000375095 / NM_001198671.2; = p.L72I on NM_174926.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/372 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.443); catalogued as COSV58754898; called by muse, mutect2, varscan2
- TMEM132B | c.2155G>A p.D719N | Missense Mutation (SNP) | VAF 91/337 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs758627102, COSV54743905, COSV54747174; called by muse, mutect2, varscan2
- TMEM135 | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV59698960; called by muse, mutect2, varscan2
- TMEM168 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV57180300; called by muse, mutect2, varscan2
- TMEM200C | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs752823779, COSV67309359; called by muse, mutect2
- TMEM41A | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53987338; called by muse, mutect2, varscan2
- TMEM63B | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.835); catalogued as COSV52478181, COSV99441103; called by muse, mutect2, varscan2
- TMEM74 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.204); catalogued as COSV52462995; called by muse, mutect2, varscan2
- TNC | c.5113A>G p.I1705V | Missense Mutation (SNP) | VAF 165/702 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60783625; called by muse, mutect2, varscan2
- TNFRSF10C | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.05); catalogued as rs755521340, COSV100790522, COSV63511528; called by muse, mutect2, varscan2
- TNS4 | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs377454691; called by muse, mutect2, varscan2
- TOGARAM1 | c.1739G>T p.R580M | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100753162; called by muse, mutect2, varscan2
- TOPBP1 | c.72del p.F24Lfs*7 | Frame Shift Del (DEL) | VAF 90/280 reads (32%) | catalogued as rs142462088; called by mutect2, pindel, varscan2
- TPPP2 | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV58794449; called by muse, mutect2, varscan2
- TRAM1 | c.632A>C p.Y211S | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51597765; called by muse, mutect2, varscan2
- TRAM1L1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs757188470, COSV60291685; called by muse, mutect2, varscan2
- TRDN | c.1655T>C p.V552A | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1466700314, COSV62118992; called by muse, mutect2, varscan2
- TRIM47 | c.1273A>G p.K425E | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV54668176; called by muse, mutect2, varscan2
- TRPC4 | c.625A>G p.I209V | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV58997417; called by muse, mutect2, varscan2
- TRPM2 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as rs1268895301, COSV55968534; called by muse, mutect2, varscan2
- TRPS1 | c.1768A>G p.S590G (on ENST00000220888 / NM_001330599.2; = p.S603G on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.484); catalogued as COSV55235926; called by muse, mutect2, varscan2
- TSHZ2 | c.2072G>A p.C691Y | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs1324720405, COSV61588225; called by muse, mutect2, varscan2
- TSPAN11 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs371115078; called by muse, mutect2, varscan2
- TSPAN2 | c.365C>G p.T122S | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1211392699, COSV101049970; called by muse, mutect2, varscan2
- TSPAN4 | c.113A>G p.Q38R | Missense Mutation (SNP) | VAF 86/289 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60258674; called by muse, mutect2, varscan2
- TTC17 | c.1246A>G p.N416D | Missense Mutation (SNP) | VAF 88/309 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.366); catalogued as rs756572599, COSV50007730; called by muse, mutect2, varscan2
- TTC23L | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV72205832; called by muse, mutect2, varscan2
- TTC7B | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 72/301 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs775846638, COSV60625244; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 37/159 reads (23%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL13P | c.149del p.N50Mfs*17 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | catalogued as rs773117671; called by mutect2, pindel, varscan2
- TTLL4 | c.430dup p.S144Kfs*71 | Frame Shift Ins (INS) | VAF 14/73 reads (19%) | catalogued as rs1183035109; called by mutect2, pindel, varscan2
- TTYH1 | c.1192T>G p.F398V | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV100002201; called by muse, mutect2, varscan2
- TXNDC2 | c.1250A>G p.D417G (on ENST00000306084 / NM_001098529.2; = p.D350G on NM_032243.6) | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1478736853, COSV60152731; called by muse, mutect2, varscan2
- TXNDC5 | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65730279; called by muse, mutect2
473 further variants in this file (208 protein-altering or splice-affecting, 238 silent, 27 other) are not listed here.
